Somatic mutation profile of tumor specimen 0DF2DL from CCDI case PBBRRE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.6 years (946 days).
Specimen 0DF2DL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eab8a20-fb13-4e88-9079-674b9cfaf9c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF2DM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/921ab8ca-969c-4432-8845-cee1c4b91b5b

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYNE1 | c.23618T>C p.I7873T (on ENST00000367255 / NM_182961.4; = p.I7802T on NM_033071.3) | Missense Mutation (SNP) | VAF 116/354 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as rs1331488136; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP2 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769812574, COSV55477350; called by muse, mutect2, varscan2
- ZIC1 | c.950A>G p.E317G | Missense Mutation (SNP) | VAF 44/524 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV51558270; called by muse, mutect2
- CFAP46 | c.446G>C p.R149P | Missense Mutation (SNP) | VAF 97/346 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERICH6B | c.905A>T p.K302M | Missense Mutation (SNP) | VAF 38/641 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.158); called by muse, mutect2
- KIF2B | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NAMPT | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 97/626 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SERPINA4 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 131/589 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSRP1 | c.24C>G p.N8K | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.071); called by muse, mutect2
- SYCP1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 123/442 reads (28%) | called by muse, mutect2, varscan2
- GMPPA | c.192C>A p.P64= | Silent (SNP) | VAF 51/591 reads (9%) | called by muse, mutect2
- NRG3 | c.1221C>G p.L407= | Silent (SNP) | VAF 147/376 reads (39%) | catalogued as COSV64580901; called by muse, mutect2, varscan2
- TMEM151B | c.1266C>T p.G422= | Silent (SNP) | VAF 113/324 reads (35%) | called by muse, mutect2, varscan2
- SPATA13 | c.290-5444dup | Intron (INS) | VAF 55/324 reads (17%) | called by mutect2, varscan2
- TYK2 | c.2467-50G>T | Intron (SNP) | VAF 8/129 reads (6%) | called by muse, mutect2
